Somatic mutation profile of tumor specimen 0DAN6G from CCDI case PBBIPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.0 years (4,377 days).
Specimen 0DAN6G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa600ed-4864-4dcd-b2da-a7f5612cc0d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAN60 (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b0eb832-d9bb-423d-bed3-57f9ded624a1

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOK2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 48/1232 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs531906443; called by muse, mutect2
- SLC30A8 | c.374C>G p.S125W | Missense Mutation (SNP) | VAF 168/552 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV69969239; called by muse, mutect2, varscan2
- RXRG | c.1129T>A p.F377I | Missense Mutation (SNP) | VAF 170/416 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHGA4 | c.336C>T p.S112= | Silent (SNP) | VAF 207/747 reads (28%) | catalogued as COSV53919235; called by muse, mutect2, varscan2
- SYF2 | c.228G>A p.E76= | Silent (SNP) | VAF 47/491 reads (10%) | catalogued as rs778503423; called by muse, mutect2
- PIAS2 | c.1041+89T>C | Intron (SNP) | VAF 15/75 reads (20%) | catalogued as rs1042326146; called by muse, mutect2, varscan2
